Gene-level copy-number profile of tumor specimen TCGA-AR-A0TQ-01A from TCGA case TCGA-AR-A0TQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 27.0 years (9,873 days).
Specimen TCGA-AR-A0TQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5d48d86f-703e-4390-a86f-c48426aa290f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d82155f8-14f0-4613-a1b1-8c1404472545

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 483; copy number 2: 50,810; copy number 3: 6,747; copy number 4: 257; copy number 5: 675; copy number 6: 153; copy number 7: 54; copy number 8: 121; copy number 10: 79; copy number 11: 164; copy number 12: 33; copy number 13: 84; copy number 14: 58; copy number 16: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TQ-01A-11D-A087-01): tumor purity 0.33, ploidy 4.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,517 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–40,390,547, 703 genes, copy number 5–6 (broad region; genes not listed).
- chr17:37,406,886–37,479,725, 3 genes, copy number 12 (within-gene range 2–12): TADA2A, AC243654.1, AC243654.2.
- chr17:38,733,898–40,061,215, 66 genes, copy number 13 (within-gene range 2–13) (broad region; genes not listed).
- chr17:51,042,524–55,173,632, 37 genes, copy number 13–16 (within-gene range 3–16): AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4.
- chr17:58,951,185–64,468,643, 190 genes, copy number 11–16 (broad region; genes not listed).
- chr17:66,197,693–70,368,916, 99 genes, copy number 5–12 (broad region; genes not listed).
- chr17:77,442,109–78,841,441, 46 genes, copy number 14 (within-gene range 3–14): Y_RNA, AC111170.3, AC111170.2, AC111170.1, AC021683.3, AC021683.2, AC021683.6, AC021683.1, AC021683.4, AC021683.5, LINC01987, LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1, DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P, SCAT1, CYTH1, AC099804.1, RNU6-638P, USP36.
- chr17:80,260,866–80,542,605, 13 genes, copy number 7: RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31.
- chr20:47,656,348–54,651,169, 137 genes, copy number 7–14 (broad region; genes not listed).
- chr20:55,997,357–60,653,784, 107 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:62,463,497–64,313,132, 116 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 483. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
